FM case AD15011 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/3ceb7066-2348-4ba9-9bb4-0a6215b068d3

Male, 73.7 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3); specimen biopsied or resected from the connective, subcutaneous and other soft tissues. Tumor nuclei on the sequenced sample's slide: 73% (pathologist estimate recorded by GDC). Sample type: Tumor.
